Surgical pathology report (de-identified scan), TCGA case TCGA-3H-AB3S, project TCGA-MESO (Mesothelioma), tissue source site MD Anderson Cancer Center, specimen TCGA-3H-AB3S-01A (Primary Tumor).

Accession: [REDACTED]
Specimen Date/Time:

DIAGNOSIS

(A) PLEURAL IMPLANT:
EPITHELIOID MALIGNANT MESOTHELIOMA.

ICD O-3
Mesothelioma, epithelial, malignant
9052/3
Site: Pleura NOS
C38.4
JF 6/13/14

GROSS DESCRIPTION

(A) PLEURAL IMPLANT – Received are four fragments of gray-white to tan-pink soft tissue ranging from 0.6 x 0.5 x 0.5 cm up to 2.0 x 1.3 x 0.6 cm. The specimen is submitted entirely.

SECTION CODE: A1, three smaller fragments; A2, A3, larger fragment serially sectioned.

CLINICAL HISTORY

None given.

SNOMED CODES

T-29000, M-90503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria	hw 3/5/14	Yes	No
Primary Tumor Site Discrepancy	not x		✓
Prior Malignancy History	yes / bladder	✓	

Source: NCI Genomic Data Commons file fa56821f-22b4-493a-817e-21a9741dbb13 (TCGA-3H-AB3S.3A7D0D05-505C-4BA4-997E-E6BC9941BA72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).